TARGET case TARGET-10-PANEHF — Acute Lymphoblastic Leukemia - Phase I (TARGET-ALL-P1)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d8ad01c7-5867-42be-9089-19762e6dc2d7

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 15 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 15.6 years (5,715 days); Year of diagnosis: 2004; Days to last follow up: 1,299 days (3.6 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (1 entry)
- Days to follow up: 1,299 days (3.6 years); Event-free: no event (relapse, second malignancy or death) recorded through day 1,299; Year of follow up: 2008.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 47.8 ×10³/µL.
- Day 8: Bone Marrow blast count 76%.
- Day 15: Bone Marrow blast count 2%.
- Day 29: Bone Marrow blast count 2%; Minimal Residual Disease (Flow Cytometry) 1.3%.
- Day 43: Bone Marrow blast count 0%.

Biospecimens (1 sample)
- Sample TARGET-10-PANEHF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_I_20230727.xlsx:
- Overall Survival Time in Days: 1299
- WBC at Diagnosis: 47.8
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 29: 1.3
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 76
- BMA Blasts Day 15: 2
- BMA Blasts Day 29: 2
- BMA Blasts Day 43: 0
- Karyotype: 46,XY,t(1;9)(q25;q34)[18]/46,XY[2]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B Cell ALL
- ALL Molecular Subtype: Other
- ALL Gene Expression Subtype: Ph-like
